Somatic mutation profile of tumor specimen MP2PRT-PARKGN-TMP1-A (aliquot MP2PRT-PARKGN-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARKGN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,439 days).
Specimen MP2PRT-PARKGN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04186a90-79e2-495c-849d-e79d70f69936.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKGN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKGN-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb4ee259-5a46-49a1-ae64-a07a91b16baa

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.85); catalogued as rs764440125, COSV55512686; called by muse, mutect2
- CCDC15 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs372616952, COSV61080279; called by muse, mutect2, varscan2
- CDR1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 318/722 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139383933, COSV65163954; called by muse, varscan2
- PDXDC1 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 348/815 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs376795176; called by muse, varscan2
- STK32A | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 99/271 reads (37%) | catalogued as rs754820325, COSV60418139, COSV60419670; called by muse, mutect2, varscan2
- WDR25 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 106/681 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs932959654; called by muse, mutect2, varscan2
